Somatic mutation profile of tumor specimen TCGA-QR-A70I-01A (aliquot TCGA-QR-A70I-01A-11D-A35D-08) from TCGA case TCGA-QR-A70I, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Extra-adrenal paraganglioma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 24.8 years (9,070 days).
Specimen TCGA-QR-A70I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4ab1980-374a-4012-a50b-5067ebb8921f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A70I-10A (Blood Derived Normal), aliquot TCGA-QR-A70I-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd14f181-a45c-45fe-9636-eb378d9973b5

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ROBO4 | c.1816C>T p.R606C | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs749338809, COSV60624136; called by muse, mutect2, varscan2
- JAK2 | c.1385A>C p.Y462S | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.148); called by muse, mutect2, varscan2
